Somatic mutation profile of tumor specimen 0DV5SH from CCDI case PBCMJC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Subependymoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,112 days).
Specimen 0DV5SH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c5e3665-a18a-4b8b-8230-7885ade737bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4249500-19b4-429e-89df-c3eb26d7f303

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCNT1 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 85/1021 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375561651; called by muse, mutect2
- GLRA3 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 52/786 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs751921093, COSV56862800; called by muse, mutect2
- ITGA2 | c.841del p.V281* | Frame Shift Del (DEL) | VAF 300/1262 reads (24%) | catalogued as COSV56868452; called by mutect2, varscan2
- SLC22A24 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 62/883 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368798118; called by muse, mutect2
- SPIRE2 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 152/619 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs762879071, COSV99643703; called by muse, mutect2, varscan2
- BRMS1L | c.727+5G>A | Splice Region (SNP) | VAF 48/1313 reads (4%) | called by muse, mutect2
- DNAH1 | c.5486C>T p.A1829V | Missense Mutation (SNP) | VAF 94/540 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL35 | c.1563+7G>A | Splice Region (SNP) | VAF 38/630 reads (6%) | called by muse, mutect2
- TPH2 | c.1006T>C p.S336P | Missense Mutation (SNP) | VAF 129/1862 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ATCAY | c.435C>T p.D145= | Silent (SNP) | VAF 44/376 reads (12%) | catalogued as rs547532756; called by muse, mutect2, varscan2
- MARCHF7 | c.237A>G p.R79= | Silent (SNP) | VAF 122/892 reads (14%) | catalogued as rs764903380; called by muse, varscan2
- SEMA3F | c.2202G>A p.L734= | Silent (SNP) | VAF 26/432 reads (6%) | called by muse, mutect2
- TLDC2 | c.366G>A p.S122= | Silent (SNP) | VAF 69/468 reads (15%) | catalogued as rs780529747, COSV54114441; called by muse, mutect2, varscan2
